Somatic mutation profile of tumor specimen 0DFMIK from CCDI case PBBSBT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.6 years (3,870 days).
Specimen 0DFMIK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 006f0866-4776-4324-a634-f9a0a547e260.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFMIL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb3d8b04-e688-41c9-9f41-3a17bde738f9

The open-access MAF lists 16 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 6, Missense Mutation 5, 3'UTR 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5532G>C p.K1844N | Missense Mutation (SNP) | VAF 36/1202 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1360182417; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 70/1336 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 48/1219 reads (4%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- PPP1R10 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 164/965 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 80/1304 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 25/316 reads (8%) | catalogued as rs1167537044; called by muse, mutect2
- CRACD | c.1887C>T p.H629= | Silent (SNP) | VAF 118/702 reads (17%) | catalogued as rs1326775684; called by muse, mutect2, varscan2
- AC005833.1 | c.*83A>T | 3'UTR (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 52/1044 reads (5%) | called by muse, mutect2
- CCDC149 | c.63+17714C>A | Intron (SNP) | VAF 23/420 reads (5%) | catalogued as rs1341369251; called by muse, mutect2
- CCDC149 | c.63+17713T>G | Intron (SNP) | VAF 24/408 reads (6%) | called by muse, mutect2
- EIF3I | c.*92T>C | 3'UTR (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 20/154 reads (13%) | catalogued as COSV99987084; called by muse, varscan2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 12/128 reads (9%) | called by muse, varscan2
- WDR45 | c.236-34C>T | Intron (SNP) | VAF 115/601 reads (19%) | called by muse, mutect2, varscan2
